Somatic mutation profile of tumor specimen C3L-01039-03 (aliquot CPT0170340036) from CPTAC case C3L-01039, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.5 years (21,733 days).
Specimen C3L-01039-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0707a8-3bd6-4ea3-8b88-3cd8c7346830.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01039-31 (Blood Derived Normal), aliquot CPT0167240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddcadeb2-b754-445f-b4e0-50525c04cf5e

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 5, Intron 3, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>C p.X153_splice | Splice Site (SNP) | VAF 15/340 reads (4%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 18/256 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- ALOX15B | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101205571, COSV66479839; called by muse, mutect2, varscan2
- ATAD1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as rs771096246; called by muse, mutect2
- CDH12 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs1291430724, COSV66409369; called by muse, mutect2
- COIL | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | catalogued as COSV53596747; called by muse, mutect2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- EFNB3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs375397163; called by muse, mutect2
- ETV6 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV56766946; called by muse, mutect2, varscan2
- GATAD1 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1261746364, COSV55319491; called by muse, mutect2
- GNL3L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as rs778008701; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs780514194; called by mutect2, varscan2
- GPR158 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1389889915; called by muse, mutect2
- IPO7 | c.3017A>G p.H1006R | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.093); catalogued as rs1431641189; called by muse, mutect2
- KBTBD3 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1232867103; called by muse, mutect2, varscan2
- MRPL21 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs768253705; called by muse, mutect2, varscan2
- MYLK | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1397757032, COSV60609666; called by muse, mutect2
- NLRP2 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs540940476; called by muse, mutect2
- PTPRT | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61969668; called by mutect2, varscan2
- SLITRK1 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 17/225 reads (8%) | catalogued as COSV100999876, COSV65674503; called by muse, mutect2
- SLITRK2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1556944777, COSV59422879; called by muse, mutect2, varscan2
- TGFBR2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | catalogued as CM076559, COSV55451791; called by muse, mutect2
- THPO | c.1193G>A p.R398H (on ENST00000649095 / NM_001290003.1; = p.R258H on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs147206404; ClinVar: uncertain significance; called by muse, mutect2
- VASN | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 10/291 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs113954688, COSV52028635; called by muse, mutect2
- ETV6 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACC1 | c.1454T>G p.F485C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PLCG1 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.036); called by muse, mutect2
- PLEKHN1 | c.1915A>T p.T639S (on ENST00000379409; = p.T587S on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PUM3 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2
- SLC7A4 | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPRY3 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- TCF20 | c.479T>C p.F160S | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TIAM1 | c.3964A>G p.I1322V | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- BACH2 | c.1779C>T p.S593= | Silent (SNP) | VAF 30/444 reads (7%) | catalogued as rs373751160; called by muse, mutect2
- DUXB | c.513C>T p.D171= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as rs774629326, COSV67756689; called by muse, mutect2
- EPPK1 | c.6336G>A p.V2112= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV73261802; called by muse, mutect2
- FREM3 | c.4878C>T p.D1626= | Silent (SNP) | VAF 16/316 reads (5%) | catalogued as rs997227800; called by muse, mutect2
- NACA | c.342C>T p.S114= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.381C>T p.N127= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs770162660, COSV53918941; called by muse, mutect2
- CSF2RA | c.*277C>T | 3'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as rs774079021; called by muse, mutect2
- F11R | c.*10G>A | 3'UTR (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- GASK1B | c.910+42T>C | Intron (SNP) | VAF 13/244 reads (5%) | called by muse, mutect2
- KCNK16 | c.803-57C>A | Intron (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- SIGIRR | c.1069+107T>G | Intron (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
